Somatic mutation profile of tumor specimen TCGA-RQ-A68N-01A (aliquot TCGA-RQ-A68N-01A-11D-A31X-10) from TCGA case TCGA-RQ-A68N, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Primary diffuse large B-cell lymphoma of the CNS; Tissue or organ of origin: Brain stem; Age at diagnosis: 63.3 years (23,127 days).
Specimen TCGA-RQ-A68N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc12fae8-2c34-4b9d-946e-21184e53f947.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RQ-A68N-10A (Blood Derived Normal), aliquot TCGA-RQ-A68N-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a64b25f2-09e7-4db5-b6c8-43ec57fd2125

The open-access MAF lists 205 somatic variants for this specimen: 154 protein-altering or splice-affecting, 50 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 50, Nonsense Mutation 12, Frame Shift Del 4, Splice Site 2, Translation Start Site 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A3 | c.7660G>A p.A2554T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786205870, CM155237, COSV55079688, COSV55087029; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TBL1XR1 | c.1337A>G p.Y446C | Missense Mutation (SNP) | VAF 118/298 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs878854402, CM164586, COSV70500760; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACB | c.1999G>A p.G667R | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs747449313, COSV100622776; called by muse, mutect2, varscan2
- ACADVL | c.298_299del p.Q100Vfs*3 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs786204713; called by pindel, varscan2
- ADGRF5 | c.1223G>T p.G408V | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51930699, COSV99345024; called by muse, mutect2, varscan2
- ADPRM | c.281T>C p.M94T | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV101126054; called by muse, mutect2
- AL121899.2 | c.1487A>G p.E496G | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV101198394; called by muse, mutect2, varscan2
- ANK1 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.363); catalogued as COSV99224169; called by muse, mutect2, varscan2
- ANKS6 | c.2554C>T p.H852Y | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV100782228; called by muse, mutect2, varscan2
- ARFGEF3 | c.4963G>A p.E1655K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs767837982, COSV52472669; called by muse, mutect2, varscan2
- ARHGAP21 | c.3997C>T p.Q1333* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as COSV100255839; called by muse, mutect2, varscan2
- ATG2A | c.5663G>C p.G1888A | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100815511; called by muse, mutect2, varscan2
- BCL11B | c.2521C>T p.R841C (on ENST00000357195 / NM_001282237.2; = p.R770C on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100595204; called by muse, mutect2, varscan2
- BNC1 | c.1180A>T p.M394L | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100596946; called by muse, mutect2, varscan2
- BPIFC | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV55910574; called by muse, mutect2, varscan2
- C15orf39 | c.1954C>T p.R652* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100641213; called by muse, mutect2, varscan2
- C18orf21 | c.322A>T p.N108Y | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99321551; called by muse, mutect2
- C7 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 33/119 reads (28%) | catalogued as COSV100495476, COSV100496548; called by muse, mutect2, varscan2
- C8A | c.1393C>T p.H465Y | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs1483234568, COSV63484731; called by muse, mutect2, varscan2
- CADM1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.364); catalogued as rs1053413125, COSV59014747; called by muse, mutect2, varscan2
- CASP1 | c.882G>A p.W294* (on ENST00000436863 / NM_033292.4; = p.W273* on NM_001223.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as COSV100782731; called by muse, mutect2, varscan2
- CAST | c.527C>T p.T176M (on ENST00000341926; = p.T259M on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as rs779432064, COSV57784671; called by muse, mutect2, varscan2
- CCDC57 | c.1978C>T p.L660F | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as rs1463687109, COSV100492408; called by muse, mutect2, varscan2
- CCER1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62645768; called by muse, mutect2
- CCN4 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs536884015, COSV51530693; called by muse, mutect2, varscan2
- CD58 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1383966385, COSV65646812; called by muse, mutect2, varscan2
- CDC16 | c.367A>T p.M123L | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99372755; called by muse, mutect2, varscan2
- CDH23 | c.4343C>T p.A1448V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1564768161, COSV99819209; called by muse, mutect2, varscan2
- CIAO3 | c.169G>C p.G57R | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52400873, COSV99284592; called by muse, mutect2, varscan2
- CNGB3 | c.1531G>T p.A511S | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV60698107; called by muse, mutect2, varscan2
- CNOT3 | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99651547; called by muse, mutect2, varscan2
- CNTNAP5 | c.3433G>T p.E1145* | Nonsense Mutation (SNP) | VAF 14/139 reads (10%) | catalogued as COSV101443128; called by muse, mutect2, varscan2
- CPNE8 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV100504003; called by muse, mutect2, varscan2
- CPXCR1 | c.878A>T p.Q293L | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99342008; called by muse, mutect2, varscan2
- CRB1 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs937362854, COSV66328905; called by muse, mutect2, varscan2
- CTNNA3 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as rs1195868563, COSV65583983; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DGKI | c.2846G>C p.G949A | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV99932712; called by muse, mutect2, varscan2
- DLGAP2 | c.2205G>A p.V735= | Splice Region (SNP) | VAF 35/85 reads (41%) | catalogued as COSV101421145; called by muse, mutect2, varscan2
- DSC3 | c.2483G>A p.R828H | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as rs747997980, COSV64574609; called by muse, mutect2, varscan2
- DST | c.20127A>C p.Q6709H (on ENST00000361203 / NM_001374722.1; = p.Q4406H on NM_015548.5) | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99751833; called by muse, mutect2, varscan2
- EPB41L1 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99149127; called by muse, mutect2, varscan2
- EXPH5 | c.5605G>A p.G1869R | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs181581015, COSV99761943; called by muse, mutect2, varscan2
- EXT1 | c.1583G>C p.R528P | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100983535, COSV65481604; called by muse, mutect2, varscan2
- FAM13C | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs534813877, COSV53252651, COSV99513189; called by muse, mutect2, varscan2
- FARP1 | c.2371C>T p.R791W | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs142251812; called by muse, mutect2, varscan2
- FAT1 | c.7814T>A p.I2605N | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101499114; called by muse, mutect2, varscan2
- FAT4 | c.5619T>A p.N1873K | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100627393; called by muse, mutect2, varscan2
- FAT4 | c.11837G>A p.C3946Y | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as COSV100627394; called by muse, mutect2, varscan2
- FLT1 | c.1602T>G p.I534M | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV56718034; called by muse, mutect2, varscan2
- GABRA1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99195727; called by muse, mutect2, varscan2
- GARRE1 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.796); catalogued as rs1213911417, COSV55097820; called by muse, mutect2
- GC | c.1074A>C p.E358D | Missense Mutation (SNP) | VAF 87/263 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.209); catalogued as COSV99909476; called by muse, mutect2, varscan2
- GPHN | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59491250; called by muse, mutect2, varscan2
- GPR101 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV53237573; called by muse, mutect2, varscan2
- H1-4 | c.139G>C p.A47P | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs547695315, COSV99175222; called by muse, mutect2, varscan2
- H1-4 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV56803422, COSV99175192; called by muse, varscan2
- H1-8 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs758365354, COSV100180381; called by muse, mutect2, varscan2
- H2AC8 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as COSV55127065; called by muse, mutect2, varscan2
- H2BC14 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.312); catalogued as rs752996565, COSV60798352; called by muse, mutect2, varscan2
- HTR2A | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 16/108 reads (15%) | catalogued as COSV101096592; called by muse, mutect2, varscan2
- IGHG2 | c.62G>A p.S21N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs772444756; called by muse, mutect2, varscan2
- IGHV2-70 | c.265A>C p.T89P | Missense Mutation (SNP) | VAF 102/284 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs373471089; called by muse, varscan2
- IGHV2-70 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs377422798; called by muse, varscan2
- IGHV2-70 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.269); catalogued as rs768517091; called by muse, varscan2
- IGKV1-17 | c.49T>C p.F17L | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756066980; called by muse, mutect2
- IGKV1-5 | c.311A>G p.D104G | Missense Mutation (SNP) | VAF 99/185 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs534822570; called by muse, mutect2, varscan2
- IGKV2-24 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs766739646; called by muse, mutect2, varscan2
- IGLV3-1 | c.151G>C p.A51P | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs376569759; called by muse, varscan2
- IGLV3-1 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs563308501; called by muse, varscan2
- IGSF8 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs775811812, COSV100081532; called by muse, mutect2, varscan2
- INKA2 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); catalogued as rs769005492, COSV100615767; called by muse, mutect2, varscan2
- IRF2 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1447797564, COSV66929557; called by muse, mutect2, varscan2
- IRF4 | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as COSV101110779; called by mutect2, varscan2
- ITIH1 | c.1143G>T p.L381F | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99834984; called by muse, mutect2, varscan2
- KCNH6 | c.2656C>G p.P886A | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV100120825, COSV59007967; called by muse, mutect2, varscan2
- KDR | c.2881C>T p.R961W | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs530419081, COSV55759748; called by muse, mutect2, varscan2
- KLRC4 | c.340+1G>C p.X114_splice | Splice Site (SNP) | VAF 53/190 reads (28%) | catalogued as COSV100511254; called by muse, mutect2
- KRT85 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV57737864; called by muse, mutect2, varscan2
- LTBP2 | c.4718C>T p.T1573M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs931485297, COSV99999820; called by muse, varscan2
- MDN1 | c.7085C>T p.S2362F | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV101020838; called by muse, mutect2, varscan2
- MTRR | c.467C>T p.A156V (on ENST00000264668; = p.A129V on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99241354; called by muse, mutect2, varscan2
- MYO3A | c.2873G>A p.R958H | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746307707, COSV56318875, COSV99780654; called by muse, mutect2, varscan2
- NCKAP5 | c.5198G>A p.R1733H | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371367810; called by muse, mutect2, varscan2
- NEB | c.13423G>A p.E4475K | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV99415934; called by muse, mutect2, varscan2
- NELFB | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1357132388, COSV100546814; called by muse, mutect2, varscan2
- NEURL4 | c.4008C>G p.S1336R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as COSV100222729, COSV59753235; called by muse, mutect2, varscan2
- NFKB2 | c.1973G>A p.R658Q | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as rs574309302, COSV50042571; called by muse, mutect2, varscan2
- NINL | c.2723G>A p.R908H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1309378093, COSV99624735; called by muse, mutect2, varscan2
- NR0B1 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 93/121 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100973459; called by muse, mutect2, varscan2
- NRAP | c.518T>C p.M173T | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV100748301; called by muse, mutect2, varscan2
- NRXN3 | c.2444C>T p.T815M (on ENST00000335750 / NM_001330195.2; = p.T442M on NM_004796.6) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs772692723, COSV59773156; called by muse, mutect2, varscan2
- NUDT22 | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99655679; called by muse, varscan2
- OLFM1 | c.1099G>A p.V367M (on ENST00000371793 / NM_001282611.2; = p.V349M on NM_014279.5) | Missense Mutation (SNP) | VAF 56/80 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs950757823, COSV99423363; called by muse, mutect2, varscan2
- OR52H1 | c.863C>A p.A288E (on ENST00000322653; = p.A294E on NM_001005289.1) | Missense Mutation (SNP) | VAF 36/254 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100497263; called by muse, varscan2
- OR52W1 | c.811C>T p.H271Y | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV100258601; called by muse, mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 30/140 reads (21%) | catalogued as rs746200712; called by mutect2, varscan2
- OR8I2 | c.181T>C p.F61L | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1187406231, COSV100135877; called by muse, mutect2, varscan2
- P2RY1 | c.383G>A p.R128K | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100521632; called by muse, mutect2, varscan2
- PCDH9 | c.3223G>T p.G1075C (on ENST00000377865 / NM_203487.3; = p.G1041C on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100118758; called by muse, mutect2, varscan2
- PCNX1 | c.3641G>A p.R1214Q | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs201430424, COSV99454349; called by muse, mutect2, varscan2
- PCSK5 | c.5276C>A p.A1759E | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV101377290; called by muse, mutect2, varscan2
- PER2 | c.2639C>T p.A880V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99611498; called by muse, mutect2, varscan2
- PHLDA1 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 7/73 reads (10%) | catalogued as COSV99876538; called by muse, mutect2
- PIM1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.249); catalogued as COSV65165136, COSV65166309; called by muse, mutect2, varscan2
- PIM1 | c.293C>A p.S98* | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | catalogued as COSV100998612, COSV65166322; called by muse, mutect2, varscan2
- PIM1 | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV65164555, COSV65164967; called by muse, mutect2, varscan2
- PLB1 | c.1083+2T>G p.X361_splice | Splice Site (SNP) | VAF 24/81 reads (30%) | catalogued as COSV100214899; called by muse, mutect2, varscan2
- PLCB1 | c.2677A>C p.K893Q | Missense Mutation (SNP) | VAF 72/436 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.031); catalogued as COSV100569587; called by muse, mutect2, varscan2
- PLCB4 | c.20T>G p.F7C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99594562; called by muse, mutect2, varscan2
- PLEC | c.10208A>G p.Q3403R (on ENST00000322810 / NM_201380.4; = p.Q3293R on NM_000445.5) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs782277164, COSV100511495; called by muse, mutect2, varscan2
- PLEC | c.974G>A p.R325K (on ENST00000322810 / NM_201380.4; = p.R215K on NM_000445.5) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100511508; called by muse, mutect2, varscan2
- POMT2 | c.1060T>C p.Y354H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99836214; called by muse, mutect2, varscan2
- PRDM1 | c.1254C>G p.Y418* | Nonsense Mutation (SNP) | VAF 20/32 reads (63%) | catalogued as COSV64845142; called by muse, mutect2, varscan2
- PRDM15 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99519434; called by muse, mutect2, varscan2
- PRDM9 | c.896G>T p.R299I | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV99689873; called by muse, mutect2, varscan2
- PRKCG | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 57/80 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV54725361; called by muse, mutect2, varscan2
- PXDNL | c.2591G>A p.R864H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62487089, COSV62489503; called by muse, mutect2, varscan2
- REEP1 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs777245164, COSV99382520; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RGS22 | c.2598C>A p.F866L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100693018; called by muse, mutect2, varscan2
- RIPK4 | c.2434C>A p.Q812K (on ENST00000352483; = p.Q764K on NM_020639.3) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as rs754331639, COSV100204688; called by muse, mutect2, varscan2
- RNF39 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); catalogued as COSV99748019; called by muse, mutect2
- ROBO2 | c.4016G>T p.G1339V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.33); catalogued as COSV100164631, COSV59936475; called by muse, mutect2, varscan2
- SLC45A1 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs370439504; called by muse, mutect2, varscan2
- SLC5A12 | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV101237592; called by muse, mutect2
- SLC5A12 | c.172A>G p.T58A | Missense Mutation (SNP) | VAF 98/205 reads (48%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.759); catalogued as COSV99744492; called by muse, mutect2, varscan2
- SLC7A13 | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs776662611, COSV99878563, COSV99879162; called by muse, mutect2, varscan2
- SSR1 | c.767T>C p.I256T | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99783617; called by muse, mutect2, varscan2
- STAT3 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as CM085729, COSV52885205; called by muse, mutect2, varscan2
- SUSD2 | c.1960C>T p.Q654* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as COSV100844191; called by muse, mutect2, varscan2
- TAS2R39 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT tolerated (0.29); PolyPhen benign (0.361); catalogued as COSV101489394; called by muse, mutect2, varscan2
- TCERG1L | c.1583A>C p.E528A | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV100893925; called by muse, mutect2, varscan2
- TMX4 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 111/411 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV99851403; called by muse, mutect2, varscan2
- TRIM71 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs376749056; called by muse, mutect2, varscan2
- TRPM3 | c.470A>G p.Y157C (on ENST00000357533 / NM_001366142.2; = p.Y2C on NM_020952.6) | Missense Mutation (SNP) | VAF 56/76 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100624164; called by muse, mutect2, varscan2
- TUBA3E | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); catalogued as rs758989528, COSV56059991; called by muse, mutect2, varscan2
- TYMP | c.515A>T p.Q172L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV99329357; called by muse, mutect2, varscan2
- UBAP2L | c.703A>G p.S235G | Missense Mutation (SNP) | VAF 93/172 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.287); catalogued as rs746323761, COSV99670668; called by muse, mutect2, varscan2
- UBL5 | c.44G>C p.R15P | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.722); catalogued as COSV100694844; called by muse, mutect2, varscan2
- UBQLN1 | c.168C>G p.S56R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99973172; called by muse, mutect2, varscan2
- USP24 | c.1332T>G p.I444M | Missense Mutation (SNP) | VAF 94/153 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV99598966; called by muse, mutect2, varscan2
- USP3 | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 92/262 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as COSV99165645; called by muse, mutect2, varscan2
- WDR88 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100866436; called by muse, mutect2, varscan2
- XRN1 | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs150688965; called by muse, mutect2, varscan2
- ZBTB49 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.163); catalogued as rs767604309, COSV61926233; called by muse, mutect2, varscan2
- ZC3H13 | c.3490C>T p.R1164* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | catalogued as COSV54452080; called by muse, mutect2, varscan2
- ZNF208 | c.869G>A p.C290Y | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101236688, COSV101236873; called by muse, mutect2, varscan2
- ZNF718 | c.524A>C p.E175A | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as COSV101210233; called by muse, mutect2, varscan2
- ZNF785 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1377687679, COSV101235639; called by muse, mutect2, varscan2
- ACACA | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- H1-4 | c.359del p.A120Vfs*109 | Frame Shift Del (DEL) | VAF 14/124 reads (11%) | called by pindel, varscan2
- IGHG2 | c.181G>T p.G61* | Nonsense Mutation (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- IGKV3-20 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 112/481 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGKV3-20 | c.78G>C p.Q26H | Missense Mutation (SNP) | VAF 81/268 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC25A5 | c.169del p.C57Afs*85 | Frame Shift Del (DEL) | VAF 27/54 reads (50%) | called by mutect2, varscan2
- ACACB | c.4708C>T p.L1570= | Silent (SNP) | VAF 4/57 reads (7%) | catalogued as COSV58143854; called by muse, mutect2
- AGAP2 | c.519C>T p.T173= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs1189383631, COSV99222343; called by muse, mutect2
- ALMS1 | c.570G>A p.L190= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV100041350; called by muse, mutect2, varscan2
- AMZ1 | c.747C>T p.A249= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100406209; called by muse, mutect2, varscan2
- ARCN1 | c.1038G>A p.L346= | Silent (SNP) | VAF 42/136 reads (31%) | catalogued as COSV99873462; called by muse, mutect2, varscan2
- BTG1 | c.141G>A p.L47= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as COSV99755334; called by muse, mutect2, varscan2
- BTG2 | c.102G>A p.R34= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs1466877644, COSV51856911, COSV99305605, COSV99305919; called by muse, mutect2, varscan2
- CARNMT1 | c.597T>C p.P199= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV100961648; called by muse, mutect2, varscan2
- CEMIP | c.1320C>T p.V440= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as COSV99586187; called by muse, mutect2, varscan2
- CNTLN | c.195C>A p.G65= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs976138213, COSV99263046; called by muse, mutect2, varscan2
- COL4A5 | c.540A>G p.G180= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as COSV100086725; called by muse, mutect2
- FCHO1 | c.2472C>T p.S824= | Silent (SNP) | VAF 25/32 reads (78%) | catalogued as rs370950809, COSV99406189; called by muse, mutect2, varscan2
- FCRL3 | c.1155C>T p.L385= | Silent (SNP) | VAF 54/95 reads (57%) | catalogued as COSV100942904; called by muse, mutect2, varscan2
- FHDC1 | c.618A>G p.S206= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV99471063; called by muse, mutect2, varscan2
- FZD10 | c.1431G>A p.A477= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs763698410, COSV99969270; called by muse, mutect2, varscan2
- GABRP | c.696G>A p.L232= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV99516617; called by muse, mutect2, varscan2
- GGA2 | c.636G>A p.R212= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs946774538, COSV100564561; called by muse, mutect2, varscan2
- GPR88 | c.184C>T p.L62= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV100159437; called by muse, mutect2, varscan2
- H2AC17 | c.348G>A p.L116= | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as rs771133764, COSV58152503; called by muse, varscan2
- H4C12 | c.175C>T p.L59= | Silent (SNP) | VAF 18/200 reads (9%) | catalogued as rs1312568654, COSV100694749; called by muse, mutect2, varscan2
- HUNK | c.732C>T p.I244= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs774875015, COSV54228777; called by muse, mutect2, varscan2
- IGKC | c.225C>T p.S75= | Silent (SNP) | VAF 22/134 reads (16%) | called by muse, mutect2, varscan2
- IGKV4-1 | c.309C>T p.S103= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as rs372416266; called by muse, mutect2, varscan2
- IGLV3-1 | c.117C>T p.I39= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs558278447; called by muse, varscan2
- LANCL3 | c.546G>A p.L182= | Silent (SNP) | VAF 57/70 reads (81%) | catalogued as COSV101065503; called by muse, mutect2, varscan2
- LRCH1 | c.402C>A p.V134= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV100243342; called by muse, mutect2, varscan2
- MARCHF11 | c.843G>A p.Q281= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV100197937, COSV60125932; called by muse, mutect2, varscan2
- NEFL | c.390C>T p.S130= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV99647849; called by muse, mutect2, varscan2
- NEK10 | c.2649C>A p.I883= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as rs939465678, COSV99834832; called by muse, mutect2, varscan2
- NMUR1 | c.600C>T p.H200= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs370312738; called by muse, mutect2, varscan2
- NOP9 | c.963A>G p.L321= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs182491838, COSV99350508; called by muse, mutect2, varscan2
- OR12D2 | c.552G>A p.K184= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV101011133; called by muse, mutect2, varscan2
- PCDHAC2 | c.414A>T p.I138= | Silent (SNP) | VAF 43/141 reads (30%) | catalogued as COSV99144542; called by muse, mutect2, varscan2
- PEX1 | c.924A>G p.K308= | Silent (SNP) | VAF 72/115 reads (63%) | catalogued as COSV99951915; called by muse, mutect2, varscan2
- PIM1 | c.51C>T p.C17= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1485392438, COSV100998611; called by muse, varscan2
- PIM1 | c.549G>A p.K183= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV100998684, COSV65166573; called by muse, mutect2, varscan2
- PPP1R9B | c.1209G>A p.E403= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100380637; called by muse, mutect2, varscan2
- RAPGEF4 | c.1962C>T p.G654= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs549829112, COSV51379199; called by muse, mutect2, varscan2
- RASSF10 | c.201C>T p.P67= | Silent (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- SCAMP1 | c.189A>C p.I63= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV100210347; called by muse, mutect2, varscan2
- SOHLH1 | c.105G>A p.S35= | Silent (SNP) | VAF 35/48 reads (73%) | catalogued as COSV100039859; called by muse, mutect2, varscan2
- SOX1 | c.111C>T p.G37= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100446815; called by mutect2, varscan2
- SPDEF | c.306G>A p.A102= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs748202781, COSV65001061; called by mutect2, varscan2
- SPPL2B | c.351C>T p.I117= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as rs374291021, COSV101194589; called by muse, mutect2, varscan2
- TIE1 | c.2223G>T p.L741= | Silent (SNP) | VAF 30/47 reads (64%) | catalogued as COSV100992010; called by muse, mutect2, varscan2
- TRPM3 | c.444A>T p.G148= (on ENST00000357533 / NM_001366142.2; = p.G117= on NM_001007471.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 116/170 reads (68%) | catalogued as COSV62468789; called by muse, mutect2, varscan2
- VPS13B | c.8400G>A p.L2800= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV100660976; called by muse, mutect2, varscan2
- WHAMM | c.2100C>T p.S700= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99724680; called by muse, varscan2
- ZDHHC7 | c.63C>T p.D21= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV100568735; called by muse, mutect2, varscan2
- ZNF319 | c.1629G>A p.K543= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99540006; called by muse, mutect2, varscan2
- ASIC2 | c.556-179730C>T | Intron (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99859437; called by muse, mutect2
